Somatic mutation profile of tumor specimen TCGA-XU-A92U-01A (aliquot TCGA-XU-A92U-01A-11D-A423-09) from TCGA case TCGA-XU-A92U, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type B2, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 67.0 years (24,487 days).
Specimen TCGA-XU-A92U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0cbaa9d7-17c3-4aca-80a4-469ceddbb1b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XU-A92U-10A (Blood Derived Normal), aliquot TCGA-XU-A92U-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea0c06d1-4c0b-4bfd-bde1-3daf79374ce1

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 7, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 36/518 reads (7%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2
- FMNL2 | c.2758C>T p.H920Y | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as rs763470402; called by mutect2, varscan2
- ARHGEF28 | c.3383C>G p.A1128G | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- HP | c.1131T>A p.F377L | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); called by muse, mutect2
- KMT2C | c.3347A>G p.N1116S | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.068); called by muse, mutect2
- KPNB1 | c.1294G>A p.V432I | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.97); PolyPhen benign (0); called by muse, mutect2
- SOX10 | c.661T>C p.S221P | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.658); called by muse, mutect2
- NCAPD3 | c.3972T>C p.H1324= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as rs773132609; called by muse, mutect2, varscan2
- UBN2 | c.2352T>A p.P784= | Silent (SNP) | VAF 5/47 reads (11%) | called by muse, mutect2, varscan2
